PECGS case C083-000046 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/535ccdb6-d760-4b1c-bac3-80b736347416

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 58 years; Year of birth: 1963; Education level: High School Graduate or GED.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 57.5 years (21,002 days); AJCC pathologic stage: Stage IIIA; Progression or recurrence: no.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000046_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000046_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
